Somatic mutation profile of tumor specimen ALCH-ADOT-TTP1-A (aliquot ALCH-ADOT-TTP1-A-1-0-D-A532-36) from ALCHEMIST case ALCH-ADOT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.5 years (19,171 days).
Specimen ALCH-ADOT-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 817c9301-798f-4017-99cc-d39de6382eb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADOT-NB1-A (Blood Derived Normal), aliquot ALCH-ADOT-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dbfa70d-9017-49c4-be4d-fa95b422e5d6

The open-access MAF lists 147 somatic variants for this specimen: 98 protein-altering or splice-affecting, 26 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 26, Intron 10, Nonsense Mutation 8, 3'UTR 5, Splice Site 4, 5'UTR 4, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP6 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 22/579 reads (4%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); catalogued as COSV100498360; called by muse, mutect2
- BRINP3 | c.511T>A p.S171T | Missense Mutation (SNP) | VAF 48/467 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV66544298; called by muse, mutect2
- BTBD11 | c.2298G>T p.E766D (on ENST00000280758 / NM_001018072.2; = p.E303D on NM_001017523.2) | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV99776359; called by muse, mutect2
- C5orf52 | c.327C>A p.S109R | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs981249398; called by muse, mutect2
- CNKSR2 | c.1512T>A p.N504K | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.077); catalogued as COSV54268618; called by muse, mutect2
- DHX8 | c.1300+2T>A p.X434_splice | Splice Site (SNP) | VAF 14/272 reads (5%) | catalogued as COSV52256115; called by muse, mutect2
- DOCK2 | c.1702C>A p.L568I | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV99910921; called by muse, mutect2
- DYM | c.1487A>T p.H496L | Missense Mutation (SNP) | VAF 22/753 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as rs1487363551; called by muse, mutect2
- EPHB1 | c.2358C>G p.I786M | Missense Mutation (SNP) | VAF 30/626 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101213867; called by muse, mutect2
- F8 | c.5981T>A p.L1994Q | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as HM060009; called by muse, mutect2
- FCRL3 | c.1304C>A p.A435D | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1385889785; called by muse, mutect2
- GABRE | c.564-1G>T p.X188_splice | Splice Site (SNP) | VAF 20/414 reads (5%) | catalogued as COSV64820449; called by muse, mutect2
- GLDC | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 30/1142 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV58679386; called by muse, mutect2
- KCNB2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 22/652 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049071, COSV73050185; called by muse, mutect2
- KIF4B | c.3671C>G p.S1224C | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV70530978; called by muse, mutect2
- KIR3DL2 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 21/674 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384615442; called by muse, mutect2
- LPAR4 | c.753C>G p.I251M | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101425150; called by muse, mutect2
- MARCHF6 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 19/369 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV56885872; called by muse, mutect2
- MYH6 | c.164A>T p.E55V | Missense Mutation (SNP) | VAF 39/900 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as rs1317811281, COSV62449877; called by muse, mutect2
- NLRP12 | c.1483C>A p.L495I | Missense Mutation (SNP) | VAF 48/1564 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60743904; called by muse, mutect2
- PAPPA2 | c.2989G>T p.G997C | Missense Mutation (SNP) | VAF 51/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100867685; called by muse, mutect2, varscan2
- RBM28 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 27/753 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1217226897, COSV56164296; called by muse, mutect2
- RYR2 | c.1777C>T p.H593Y | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1343929904; called by muse, mutect2
- RYR2 | c.14000G>T p.S4667I | Missense Mutation (SNP) | VAF 38/449 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs1057523888, COSV63684161; ClinVar: uncertain significance; called by muse, mutect2
- TRAV7 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 22/339 reads (6%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); catalogued as rs1342369948; called by muse, mutect2
- UACA | c.2773C>A p.L925M | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.338); catalogued as COSV59859784; called by muse, mutect2
- UGT1A1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 43/1093 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as CD146214; called by muse, mutect2
- VCAN | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1288312945; called by muse, mutect2
- ZNF81 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 33/614 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs782354746; called by muse, mutect2
- ABCB7 | c.367G>T p.A123S (on ENST00000373394 / NM_001271696.3; = p.A124S on NM_004299.6) | Missense Mutation (SNP) | VAF 22/613 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.011); called by muse, mutect2
- ADAM15 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 68/679 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK1 | c.5347G>A p.E1783K | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ANKFN1 | c.3193G>C p.D1065H (on ENST00000653862; = p.D918H on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANO3 | c.2362A>T p.R788W | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APOB | c.5361G>T p.Q1787H | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- ARX | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 21/413 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2
- C16orf96 | c.2256G>T p.E752D | Missense Mutation (SNP) | VAF 14/325 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- C8B | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 34/663 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CACNA1E | c.5292G>T p.M1764I | Missense Mutation (SNP) | VAF 23/361 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- CACNB1 | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.027); called by muse, mutect2
- CDH23 | c.5856G>T p.E1952D | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.755); called by muse, mutect2
- CKAP5 | c.5740A>C p.T1914P (on ENST00000529230 / NM_001008938.4; = p.T1854P on NM_014756.3) | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2
- CLVS2 | c.129C>A p.D43E | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL1A1 | c.1921G>T p.G641* | Nonsense Mutation (SNP) | VAF 27/971 reads (3%) | called by muse, mutect2
- CSPP1 | c.3116A>G p.D1039G (on ENST00000676605; = p.D998G on NM_024790.6) | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2
- DCT | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 26/419 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.384); called by muse, mutect2
- DHRS9 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2
- EXO1 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 20/488 reads (4%) | called by muse, mutect2
- EYS | c.3587G>C p.C1196S | Missense Mutation (SNP) | VAF 15/547 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- EYS | c.1844C>G p.S615* | Nonsense Mutation (SNP) | VAF 20/392 reads (5%) | called by muse, mutect2
- F13A1 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 30/584 reads (5%) | called by muse, mutect2
- FAAH2 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 30/511 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- FAM24A | c.8A>T p.K3M | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2
- FLG2 | c.1339T>C p.C447R | Missense Mutation (SNP) | VAF 55/563 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- FUCA1 | c.1072G>T p.V358F | Missense Mutation (SNP) | VAF 22/514 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2
- GABRB2 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GCNT4 | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 33/450 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- GSPT2 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2
- GUCY1A2 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCRTR2 | c.761A>C p.Q254P | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2
- HMCN1 | c.15647G>A p.G5216E | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.947); called by muse, mutect2
- HRC | c.249G>A p.W83* | Nonsense Mutation (SNP) | VAF 37/847 reads (4%) | called by muse, mutect2
- HTR5A | c.590A>T p.E197V | Missense Mutation (SNP) | VAF 20/596 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ING3 | c.436+1G>T p.X146_splice | Splice Site (SNP) | VAF 22/478 reads (5%) | called by muse, mutect2
- IQSEC2 | c.1747G>T p.D583Y (on ENST00000642864 / NM_001111125.3; = p.D378Y on NM_015075.2) | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- KIAA1549L | c.2183T>A p.M728K (on ENST00000321505; = p.M1025K on NM_012194.3) | Missense Mutation (SNP) | VAF 37/1023 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2
- LAMA3 | c.1492G>T p.V498F | Missense Mutation (SNP) | VAF 42/1082 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); called by muse, mutect2
- LGI3 | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.911); called by muse, mutect2
- MED14 | c.2800G>C p.V934L | Missense Mutation (SNP) | VAF 28/864 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- MEGF11 | c.164C>A p.T55K | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.221); called by muse, mutect2
- MRPS30 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 33/958 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH2 | c.5545C>G p.H1849D | Missense Mutation (SNP) | VAF 36/1193 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.217); called by muse, mutect2
- MYH4 | c.5200C>A p.L1734M | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.511); called by muse, mutect2
- NTNG1 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 24/601 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OLFML1 | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- OR51E2 | c.558G>T p.L186F | Missense Mutation (SNP) | VAF 25/498 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ROR2 | c.2077G>C p.D693H | Missense Mutation (SNP) | VAF 18/490 reads (4%) | PolyPhen benign (0.206); called by muse, mutect2
- RYR2 | c.12497A>T p.K4166M | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SCART1 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 30/586 reads (5%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.535); called by muse, mutect2
- SCNN1B | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SETBP1 | c.3893G>T p.S1298I | Missense Mutation (SNP) | VAF 17/456 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- SH3TC2 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 25/518 reads (5%) | called by muse, mutect2
- SLAMF1 | c.165C>A p.S55R | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2
- SNX24 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- SOX5 | c.1867T>C p.Y623H | Missense Mutation (SNP) | VAF 38/1011 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SOX6 | c.2471C>T p.A824V (on ENST00000528429 / NM_001145819.2; = p.A797V on NM_017508.3) | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.046); called by muse, mutect2
- ST18 | c.2329G>T p.G777W | Missense Mutation (SNP) | VAF 21/527 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUPT20HL1 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 33/891 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TCF12 | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 33/750 reads (4%) | called by muse, mutect2
- TMCO5A | c.316-1G>T p.X106_splice | Splice Site (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- TP63 | c.535G>T p.V179L | Missense Mutation (SNP) | VAF 18/557 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM62 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIO | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 22/681 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- TTPA | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 16/437 reads (4%) | called by muse, mutect2
- UBE4B | c.101G>T p.R34M | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- USP18 | c.532T>G p.C178G | Missense Mutation (SNP) | VAF 13/382 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF223 | c.1202A>T p.N401I | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZSCAN23 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- ABCA6 | c.4083A>G p.Q1361= | Silent (SNP) | VAF 22/656 reads (3%) | catalogued as COSV99446769; called by muse, mutect2
- ASPDH | c.291C>A p.S97= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- BCORL1 | c.2076G>A p.E692= | Silent (SNP) | VAF 17/522 reads (3%) | called by muse, mutect2
- DTNA | c.669C>A p.V223= | Silent (SNP) | VAF 31/554 reads (6%) | called by muse, mutect2
- FAT2 | c.8511T>A p.S2837= | Silent (SNP) | VAF 14/249 reads (6%) | called by muse, mutect2
- FBXO34 | c.1548G>T p.G516= | Silent (SNP) | VAF 22/441 reads (5%) | called by muse, mutect2
- FPR1 | c.207G>T p.V69= | Silent (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- GMCL2 | c.735T>C p.N245= | Silent (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- GPX5 | c.327A>T p.P109= | Silent (SNP) | VAF 66/708 reads (9%) | called by muse, mutect2
- IL12RB1 | c.984G>T p.L328= | Silent (SNP) | VAF 29/568 reads (5%) | called by muse, mutect2
- KMT2A | c.7650A>T p.I2550= | Silent (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- LIN28B | c.6C>A p.A2= | Silent (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- OPN4 | c.117G>T p.L39= | Silent (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- OR11G2 | c.534C>G p.L178= | Silent (SNP) | VAF 19/456 reads (4%) | called by muse, mutect2
- PCDHA7 | c.2100G>T p.L700= | Silent (SNP) | VAF 32/324 reads (10%) | catalogued as COSV65340548; called by muse, mutect2
- PCDHB8 | c.543C>A p.V181= | Silent (SNP) | VAF 29/644 reads (5%) | called by muse, mutect2
- PCDHGA3 | c.1740C>A p.R580= | Silent (SNP) | VAF 27/568 reads (5%) | called by muse, mutect2
- RHEX | c.168C>T p.S56= | Silent (SNP) | VAF 37/572 reads (6%) | called by muse, mutect2
- SALL4 | c.2169G>T p.G723= | Silent (SNP) | VAF 34/784 reads (4%) | called by muse, mutect2
- SEMA6A | c.2085C>A p.R695= | Silent (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- SERPINA3 | c.1188C>T p.N396= | Silent (SNP) | VAF 28/804 reads (3%) | called by muse, mutect2
- STS | c.858A>T p.T286= | Silent (SNP) | VAF 28/698 reads (4%) | called by muse, mutect2
- VAX1 | c.238C>A p.R80= | Silent (SNP) | VAF 17/514 reads (3%) | called by muse, mutect2
- VIL1 | c.54G>T p.G18= | Silent (SNP) | VAF 26/530 reads (5%) | called by muse, mutect2
- ZNF25 | c.1212G>T p.G404= | Silent (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- ZNF451 | c.2760C>T p.N920= (on ENST00000370706 / NM_001031623.3; = p.N872= on NM_015555.2) | Silent (SNP) | VAF 7/125 reads (6%) | catalogued as rs1415481778; called by muse, mutect2
- ABLIM1 | c.1041+2656C>T | Intron (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2
- AC093155.3 | c.767-1451G>T | Intron (SNP) | VAF 19/449 reads (4%) | called by muse, mutect2
- ATP2B2 | c.*119C>T | 3'UTR (SNP) | VAF 23/517 reads (4%) | catalogued as COSV59502960; called by muse, mutect2
- CDH26 | c.1889-65T>C | Intron (SNP) | VAF 19/550 reads (3%) | called by muse, mutect2
- COL9A3 | c.1604-39C>T | Intron (SNP) | VAF 20/632 reads (3%) | catalogued as rs1198779198; called by muse, mutect2
- IZUMO3 | c.-220C>A | 5'UTR (SNP) | VAF 14/290 reads (5%) | catalogued as rs1220117492; called by muse, mutect2
- KLF6 | c.*1978G>A | 3'UTR (SNP) | VAF 16/481 reads (3%) | called by muse, mutect2
- LDAH | c.298+1070G>T | Intron (SNP) | VAF 25/769 reads (3%) | catalogued as rs1269360027; called by muse, mutect2
- LINC01511 | n.437-8415G>T | Intron (SNP) | VAF 38/614 reads (6%) | called by muse, mutect2
- LIPI | c.-10G>T | 5'UTR (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- LIPI | c.-11G>A | 5'UTR (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- MCFD2 | c.309+46C>T | Intron (SNP) | VAF 15/410 reads (4%) | catalogued as rs1026792937; called by muse, mutect2
- NAMPTP1 | n.265T>C | RNA (SNP) | VAF 40/530 reads (8%) | called by muse, mutect2
- PDHA1 | c.*33G>T | 3'UTR (SNP) | VAF 28/528 reads (5%) | called by muse, mutect2
- RNF10 | c.157+4499G>T | Intron (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- SIRPB2 | c.859+112C>A | Intron (SNP) | VAF 24/502 reads (5%) | called by muse, mutect2
- SYP | c.*4+10C>A | Intron (SNP) | VAF 22/535 reads (4%) | catalogued as rs781803684; called by muse, mutect2
- TAC3 | chr12:57016531 C>A | 5'Flank (SNP) | VAF 16/298 reads (5%) | called by muse, mutect2
- VMA21 | c.-23G>C | 5'UTR (SNP) | VAF 12/255 reads (5%) | called by muse, mutect2
- VSIG10L | c.*119G>T | 3'UTR (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- ZNF503-AS2 | n.634G>T | RNA (SNP) | VAF 52/894 reads (6%) | called by muse, mutect2
- ZNF835 | c.*1G>T | 3'UTR (SNP) | VAF 28/505 reads (6%) | catalogued as COSV101606363; called by muse, mutect2
- ZSCAN16 | chr6:28123172 C>A | 5'Flank (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
